Somatic mutation profile of tumor specimen TCGA-A3-A6NL-01A (aliquot TCGA-A3-A6NL-01A-11D-A33K-10) from TCGA case TCGA-A3-A6NL, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 49.1 years (17,952 days).
Specimen TCGA-A3-A6NL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf1970fa-82c4-45c1-b619-0d0b025365ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-A6NL-10A (Blood Derived Normal), aliquot TCGA-A3-A6NL-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b08bdbf1-9fef-443c-a3c1-a88b1380eac1

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 21, Silent 11, Nonsense Mutation 4, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.1667C>A p.S556* | Nonsense Mutation (SNP) | VAF 16/85 reads (19%) | catalogued as COSV99710536; called by muse, mutect2, varscan2
- BAIAP3 | c.2969G>A p.R990H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.575); catalogued as rs377365128; called by mutect2, varscan2
- CLCN7 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99246994; called by muse, mutect2, varscan2
- CTSW | c.890G>C p.G297A | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100327241; called by muse, mutect2, varscan2
- DSCAM | c.874G>C p.V292L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as COSV101259532; called by muse, mutect2, varscan2
- EMP1 | c.241G>C p.V81L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV99916873; called by muse, mutect2, varscan2
- F11 | c.1196G>A p.W399* | Nonsense Mutation (SNP) | VAF 41/102 reads (40%) | catalogued as rs1561489647, CM090244, COSV99250740; called by muse, mutect2, varscan2
- FAM163B | c.425A>G p.Q142R | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100618943; called by muse, mutect2
- FGGY | c.935T>A p.V312D | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100364057; called by muse, mutect2, varscan2
- GJA8 | c.769G>C p.V257L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV99569218; called by muse, mutect2, varscan2
- HS6ST3 | c.506T>C p.I169T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100940171; called by muse, mutect2, varscan2
- NAT8L | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as rs1309041395, COSV59051230; called by mutect2, varscan2
- OR4C3 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100167627; called by muse, mutect2, varscan2
- PON3 | c.1003G>C p.V335L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1353589511, COSV99672337; called by muse, mutect2, varscan2
- PTCD3 | c.1874C>G p.S625C | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as COSV99606164; called by muse, mutect2, varscan2
- RYR2 | c.5750A>C p.Q1917P | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV100768914; called by muse, mutect2, varscan2
- SMG9 | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs759730335, COSV99526664; called by muse, mutect2, varscan2
- SVOPL | c.1353+1G>A p.X451_splice (on ENST00000419765; = p.X299_splice on NM_174959.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99939149; called by muse, mutect2, varscan2
- TAPT1 | c.1242C>G p.I414M | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV100461041; called by muse, mutect2, varscan2
- TMEM242 | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100900882; called by muse, mutect2, varscan2
- TMEM242 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.447); catalogued as COSV100900884; called by muse, mutect2, varscan2
- TUBGCP6 | c.253A>C p.K85Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV99352208; called by muse, mutect2, varscan2
- UTRN | c.7114A>T p.K2372* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV100839734; called by muse, varscan2
- VPS45 | c.1358T>G p.L453R | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as COSV100964875; called by muse, mutect2
- ZNF143 | c.1216A>T p.K406* | Nonsense Mutation (SNP) | VAF 27/99 reads (27%) | catalogued as COSV100217759; called by muse, mutect2, varscan2
- ZYG11B | c.974C>A p.T325N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV99597036; called by muse, mutect2, varscan2
- IFIT1 | c.1238del p.L413* | Frame Shift Del (DEL) | VAF 17/119 reads (14%) | called by pindel, varscan2
- ADCY4 | c.396C>T p.A132= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as rs1344643051, COSV99353048; called by muse, mutect2, varscan2
- ALDH2 | c.657C>G p.L219= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as COSV99922794; called by muse, mutect2, varscan2
- BRD2 | c.87A>G p.P29= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100875598; called by muse, mutect2, varscan2
- EPB41 | c.297C>G p.G99= | Silent (SNP) | VAF 43/232 reads (19%) | catalogued as COSV100548274; called by muse, mutect2, varscan2
- FGGY | c.936C>G p.V312= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV100364058; called by muse, mutect2, varscan2
- MLH3 | c.3396T>C p.T1132= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV99469837; called by muse, mutect2, varscan2
- SLAIN1 | c.1536T>C p.A512= (on ENST00000466548; = p.A249= on NM_144595.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs774398950, COSV99935051; called by muse, mutect2, varscan2
- SLC25A17 | c.732G>A p.L244= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99610546; called by muse, mutect2, varscan2
- SLC38A10 | c.459C>T p.F153= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as rs1467224327, COSV99917293; called by muse, mutect2, varscan2
- SNX4 | c.618G>A p.A206= | Silent (SNP) | VAF 44/198 reads (22%) | catalogued as rs73862103, COSV52540207; called by muse, mutect2, varscan2
- ZNF45 | c.1116T>A p.G372= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99524081; called by muse, mutect2, varscan2
